Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5763, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5763-01A (Primary Tumor).

Diagnosis

1. Predominantly moderately differentiated bilateral multifocal adenocarcinoma of the prostate in the peripheral zone (Gleason 3+4=7, Gleason 4: 30%). Maximum tumor diameter 1.6 cm. Tumor infiltration of periprostatic fatty tissue in the left basal and left rectolateral region (invasion front 1 mm, max. 0.2 mm depth) and the right basal region (invasion front 1 mm, max. 0.2 mm depth). Extensive multifocal tumor involvement of perineural sheaths. Tumor-free surgical preparation margins.

Additional foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of the prostatic urethra without dysplasia.

Tumor-free, regular seminal vesicles and seminal ducts.

2. Lymph nodes on the right: four tumor-free lymph nodes (0/4).

3. Lymph nodes on the left: one tumor-free lymph node (0/1).

Summary tumor classification:

pT3a, max. tumor diameter 16 mm, Gleason 3+4=7 (Gleason 4: 30%), pN0 (0/5), R0.

Remark

Tumor portions were identified in the region of the yellow-labeled artefactual preparation margins in the left rectolateral region. However, the surgical blue and green-labeled preparation margins are tumor-free and, together with the prior frozen section analysis, the tumor can be assumed to have been completely excised.

The Gleason 4 portion was already seen in the preliminary punch biopsy.

Immunohistochemical investigations were initiated to establish whether there was any tumorous vessel invasion, the results of which will be presented in a follow-up report.

Follow-up report**Microscopy**

1. Immunohistochemistry: CD31, D2-40, 2 blocks

Communicated tumor classification:

pT3a, max. tumor diameter 16 mm, Gleason 3+4=7 (Gleason 4: 30%), pN0 (0/5), R0.

Immunohistochemical investigation of two representative tumor blocks showed no evidence of blood or lymph vessel invasion.

Summary tumor classification:

pT3a, max. tumor diameter 16 mm, Gleason 3+4=7 (Gleason 4: 30%), L0/V0, pN0 (0/5), R0.

Source: NCI Genomic Data Commons file 84c2213a-1e7d-4727-befc-ab1c4706462d (TCGA-CH-5763.8722BFBE-6DB5-41CA-9AC4-004B999A772D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).